CGCI case HTMCP-02-03-01011 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/d8b539c9-0bd3-478b-8c5a-b2d03522c2d7

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample HTMCP-02-03-01011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01011-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
